Somatic mutation profile of tumor specimen C3L-08256-05 (aliquot CPT0457110009) from CPTAC case C3L-08256, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 64.4 years (23,530 days).
Specimen C3L-08256-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64997989-dfc0-419d-985e-6406aeee6c57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08256-31 (Blood Derived Normal), aliquot CPT0457220003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47ae43d2-657c-4d91-8682-9ec9ea3d76e8

The open-access MAF lists 380 somatic variants for this specimen: 258 protein-altering or splice-affecting, 108 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 241, Silent 108, Nonsense Mutation 13, Intron 9, 3'UTR 2, Frame Shift Del 2, RNA 2, Splice Site 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/226 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL4A1 | c.3674G>A p.G1225E | Missense Mutation (SNP) | VAF 216/565 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555302454, COSV65426702; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP6C | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 153/248 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733111, COSV65207035; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 172/412 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.372); catalogued as rs865773772, COSV100822112; called by muse, mutect2, varscan2
- AKR1D1 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54341172; called by muse, mutect2, varscan2
- APOB | c.8977G>A p.D2993N | Missense Mutation (SNP) | VAF 154/406 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs1046539639, COSV51938081, COSV51941541; called by muse, mutect2, varscan2
- AREG | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 155/362 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV99144397; called by muse, mutect2, varscan2
- BHMT | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV57153540; called by muse, mutect2, varscan2
- BTBD11 | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 217/520 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.033); catalogued as rs780937911; called by muse, mutect2
- CACNA1E | c.4466C>T p.A1489V | Missense Mutation (SNP) | VAF 95/366 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV62425898; called by muse, mutect2, varscan2
- CAMSAP3 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 158/491 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV50332766; called by muse, mutect2, varscan2
- CATSPER4 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs574897954, COSV58792452; called by muse, mutect2, varscan2
- CCDC159 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 163/364 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as rs1207614963; called by muse, mutect2, varscan2
- CCDC73 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58795949; called by muse, mutect2, varscan2
- CD248 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 239/620 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs138260039, COSV60937524; called by muse, mutect2
- CDHR5 | c.1957G>A p.E653K (on ENST00000358353 / NM_001171968.2; = p.E659K on NM_021924.5) | Missense Mutation (SNP) | VAF 164/448 reads (37%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.636); catalogued as COSV100363857, COSV57645384; called by muse, varscan2
- CDSN | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 179/599 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.029); catalogued as rs1471036139; called by muse, mutect2, varscan2
- CELSR1 | c.9026C>T p.S3009F | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs1218540124; called by muse, mutect2, varscan2
- CIC | c.3839G>A p.G1280E | Missense Mutation (SNP) | VAF 198/519 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs1370848225; called by muse, mutect2, varscan2
- CLEC10A | c.754G>A p.D252N (on ENST00000254868 / NM_182906.4; = p.D228N on NM_006344.4) | Missense Mutation (SNP) | VAF 275/470 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1235082203, COSV54700356; called by muse, mutect2, varscan2
- CLEC4F | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 113/328 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as rs1553395944; called by muse, mutect2, varscan2
- COL10A1 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 350/626 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773712834; called by muse, mutect2, varscan2
- CRYBG1 | c.4847G>A p.G1616D | Missense Mutation (SNP) | VAF 82/326 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747913472; called by muse, mutect2, varscan2
- CRYGD | c.206G>A p.W69* | Nonsense Mutation (SNP) | VAF 70/253 reads (28%) | catalogued as rs1042097771; called by muse, mutect2, varscan2
- CSMD3 | c.5498G>A p.G1833E (on ENST00000297405 / NM_001363185.1; = p.G1729E on NM_052900.3) | Missense Mutation (SNP) | VAF 289/439 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52292825, COSV99841525; called by muse, mutect2, varscan2
- CSNK2A2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 96/262 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs1431525244, COSV52640977; called by muse, mutect2, varscan2
- CTCFL | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 183/463 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs1374671948; called by muse, mutect2, varscan2
- CTSE | c.1183G>A p.G395R (on ENST00000360218; = p.G390R on NM_001910.4) | Missense Mutation (SNP) | VAF 117/458 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63060072; called by muse, mutect2, varscan2
- CYLC1 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 133/216 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV61411138; called by muse, mutect2, varscan2
- DCAF10 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 136/213 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV54292166; called by muse, mutect2, varscan2
- DIRAS2 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 100/193 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV65370776; called by muse, mutect2, varscan2
- DOCK3 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 77/241 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1449050607, COSV56552226; called by muse, mutect2, varscan2
- ENPP5 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 196/655 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.05); catalogued as COSV57908207; called by muse, mutect2, varscan2
- FAM160A1 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 169/433 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs762910517; called by muse, mutect2, varscan2
- FGA | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 78/233 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV57397265; called by muse, mutect2, varscan2
- FGF4 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 149/410 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866953016, COSV51449981; called by muse, mutect2, varscan2
- FGF4 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 181/493 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1401631287; called by muse, mutect2, varscan2
- FLG | c.8543G>A p.G2848E | Missense Mutation (SNP) | VAF 171/946 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs759162835; called by muse, mutect2, varscan2
- G2E3 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474843475; called by muse, mutect2, varscan2
- GIMAP2 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 145/397 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56235816; called by muse, mutect2, varscan2
- GLB1L3 | c.1785G>A p.W595* | Nonsense Mutation (SNP) | VAF 69/204 reads (34%) | catalogued as COSV68392717; called by muse, mutect2
- GPR20 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 195/797 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.045); catalogued as COSV66684344; called by muse, mutect2, varscan2
- GPR37L1 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 190/717 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs368393555; called by muse, mutect2, varscan2
- GPR84 | c.167A>G p.N56S | Missense Mutation (SNP) | VAF 168/434 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1451212407; called by muse, mutect2, varscan2
- GPRC6A | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 267/462 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775109241, COSV59951289; called by muse, mutect2, varscan2
- GPX2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 118/282 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs777293546; called by muse, mutect2, varscan2
- GRID2 | c.1817A>G p.Y606C | Missense Mutation (SNP) | VAF 94/273 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs777890523; called by muse, mutect2, varscan2
- GRIN2A | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 152/404 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58036919; called by muse, mutect2, varscan2
- HTN1 | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.267); catalogued as rs1416979116; called by muse, mutect2, varscan2
- HYDIN | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 122/346 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55491428; called by muse, mutect2, varscan2
- IGKV2D-24 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.125); catalogued as rs1346659808; called by muse, mutect2, varscan2
- JAK2 | c.3344C>A p.S1115Y | Missense Mutation (SNP) | VAF 76/131 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.435); catalogued as COSV101071607; called by muse, mutect2, varscan2
- KDM2B | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 178/500 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs895569064, COSV65639369; called by muse, mutect2, varscan2
- KIAA1549L | c.1884G>A p.A628= (on ENST00000321505; = p.A925= on NM_012194.3) | Splice Region (SNP) | VAF 90/235 reads (38%) | catalogued as rs770364632; called by muse, mutect2, varscan2
- KLHDC7A | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 144/404 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.194); catalogued as rs373822925; called by muse, mutect2, varscan2
- KMT2D | c.7169C>T p.P2390L | Missense Mutation (SNP) | VAF 160/536 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs866926540, COSV56432484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2D | c.7168C>T p.P2390S | Missense Mutation (SNP) | VAF 159/537 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.037); catalogued as rs1464442467; called by muse, mutect2, varscan2
- LAMA5 | c.6538C>T p.R2180W | Missense Mutation (SNP) | VAF 135/403 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs199798998, COSV53361362; called by muse, mutect2, varscan2
- LAMB4 | c.4382G>A p.R1461K | Missense Mutation (SNP) | VAF 104/306 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV52719931; called by muse, mutect2, varscan2
- LMOD2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 190/490 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV71755639; called by muse, mutect2, varscan2
- LRTM1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 162/449 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV55580946; called by muse, mutect2, varscan2
- MAGEE2 | c.836G>A p.W279* | Nonsense Mutation (SNP) | VAF 173/285 reads (61%) | catalogued as rs756674679, COSV64897829; called by muse, mutect2, varscan2
- MAP3K20 | c.1054G>C p.V352L | Missense Mutation (SNP) | VAF 111/327 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.098); catalogued as COSV64380045; called by muse, mutect2, varscan2
- MAPK13 | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 102/431 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV52983699; called by muse, mutect2, varscan2
- MDGA2 | c.1825C>T p.P609S (on ENST00000399232 / NM_001113498.2; = p.P311S on NM_182830.4) | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs377249612, COSV62115359; called by muse, mutect2, varscan2
- ME2 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58422563; called by muse, mutect2, varscan2
- MUSK | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 156/243 reads (64%) | SIFT tolerated (0.48); PolyPhen benign (0.174); catalogued as COSV51883473; called by muse, mutect2, varscan2
- MYH13 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 213/397 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768776843, COSV52828318; called by muse, mutect2, varscan2
- MYO15A | c.3070C>T p.P1024S | Missense Mutation (SNP) | VAF 206/814 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as rs369693669; called by muse, mutect2, varscan2
- NLRP11 | c.2861C>T p.P954L | Missense Mutation (SNP) | VAF 92/238 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.306); catalogued as COSV64088613; called by muse, mutect2
- NOC4L | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 124/323 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368824768; called by muse, mutect2, varscan2
- OPRPN | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 179/458 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); catalogued as COSV68192778; called by muse, mutect2, varscan2
- OR10H1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 131/412 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100612381; called by muse, mutect2, varscan2
- OR4C3 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 200/455 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60584139, COSV60585481; called by muse, mutect2, varscan2
- OR52B2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 165/449 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs576770117, COSV73209393; called by muse, mutect2, varscan2
- PCDHGA7 | c.2273C>T p.S758F | Missense Mutation (SNP) | VAF 104/326 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.495); catalogued as rs1013319688, COSV53912978, COSV99529756; called by muse, mutect2, varscan2
- PDE6C | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 177/231 reads (77%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as rs148611776; called by muse, mutect2, varscan2
- PDGFRB | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 121/302 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1167658274, COSV55804044; called by muse, mutect2, varscan2
- PER3 | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 206/527 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV100728313; called by muse, mutect2, varscan2
- PIEZO2 | c.7763C>T p.P2588L | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53291026; called by muse, mutect2, varscan2
- PKHD1L1 | c.8191C>T p.P2731S | Missense Mutation (SNP) | VAF 138/671 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65754421; called by muse, mutect2, varscan2
- PKHD1L1 | c.8192C>T p.P2731L | Missense Mutation (SNP) | VAF 137/673 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65740474; called by muse, mutect2, varscan2
- PLD4 | c.1204G>C p.A402P | Missense Mutation (SNP) | VAF 138/367 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV101190470; called by muse, mutect2, varscan2
- PLG | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 129/312 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV51982153; called by muse, mutect2, varscan2
- PPFIBP2 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 140/369 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV55082129; called by muse, mutect2, varscan2
- PTGFR | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 157/424 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as rs1259928177, COSV66115350; called by muse, mutect2, varscan2
- PYGM | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755309894; called by muse, mutect2, varscan2
- RASIP1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 166/446 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55808112; called by muse, mutect2, varscan2
- RNASE3 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 168/473 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.094); catalogued as rs760744021; called by muse, mutect2, varscan2
- RNF126 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 118/309 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193176146; called by muse, mutect2, varscan2
- RNF214 | c.1753C>G p.R585G | Missense Mutation (SNP) | VAF 139/351 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56119982, COSV56120060; called by muse, mutect2, varscan2
- RPGRIP1L | c.3539G>A p.S1180N | Missense Mutation (SNP) | VAF 129/373 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767972738; called by muse, mutect2, varscan2
- RYR3 | c.5608C>T p.P1870S | Missense Mutation (SNP) | VAF 105/267 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1043367167; called by muse, mutect2, varscan2
- SCN11A | c.2462G>A p.G821E | Missense Mutation (SNP) | VAF 112/296 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV56567663; called by muse, varscan2
- SCN3B | c.282G>A p.W94* | Nonsense Mutation (SNP) | VAF 128/345 reads (37%) | catalogued as rs1555115600; called by muse, mutect2, varscan2
- SEMA3D | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as COSV52404058; called by muse, mutect2, varscan2
- SF3B1 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 111/316 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as rs1406033605; called by muse, mutect2, varscan2
- SLC22A13 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 194/508 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs140006225; called by muse, mutect2, varscan2
- SPTA1 | c.6272C>T p.S2091F | Missense Mutation (SNP) | VAF 297/586 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934746; called by muse, mutect2, varscan2
- STARD13 | c.2077G>A p.D693N (on ENST00000336934 / NM_001243476.3; = p.D575N on NM_052851.3) | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs754311830, COSV55230061, COSV55231307, COSV55232036; called by muse, mutect2, varscan2
- TAFA1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 121/323 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1055625351, COSV72037141; called by muse, mutect2, varscan2
- TBC1D14 | c.1819T>C p.F607L | Missense Mutation (SNP) | VAF 152/379 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV68986540; called by muse, mutect2, varscan2
- TBX19 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 125/456 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs746057850, COSV63198717; called by muse, mutect2, varscan2
- TEX11 | c.991C>T p.L331F (on ENST00000344304; = p.L316F on NM_031276.3) | Missense Mutation (SNP) | VAF 122/192 reads (64%) | SIFT tolerated (0.72); PolyPhen benign (0.078); catalogued as COSV60226708; called by muse, mutect2, varscan2
- TMCO3 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 99/255 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs764955516; called by muse, mutect2, varscan2
- TMEM74B | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 217/344 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1489124182; called by muse, mutect2, varscan2
- TNFRSF8 | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 149/372 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as rs1378224648, COSV55795067; called by muse, mutect2, varscan2
- TNN | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 183/621 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs747301590, COSV53435407, COSV99511691; called by muse, mutect2, varscan2
- TRHR | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 379/598 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61232863; called by muse, mutect2, varscan2
- TTC29 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 102/219 reads (47%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV57275392; called by muse, mutect2, varscan2
- TUT4 | c.3580C>T p.R1194C | Missense Mutation (SNP) | VAF 129/344 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57118100; called by muse, mutect2, varscan2
- TXLNB | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 190/459 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771691923; called by muse, mutect2, varscan2
- TYK2 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 92/276 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747918278, COSV53389192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT1A4 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 150/508 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756696112; called by muse, mutect2, varscan2
- UGT3A1 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV57102201; called by muse, mutect2, varscan2
- WFS1 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 202/524 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as rs1477447848; called by muse, mutect2
- ZBBX | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 85/256 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as rs771044704; called by muse, mutect2, varscan2
- ZNF208 | c.2899C>T p.H967Y | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1568443528; called by muse, mutect2, varscan2
- ZNF287 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 267/463 reads (58%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as COSV67688115; called by muse, mutect2, varscan2
- ZNF341 | c.1387C>T p.H463Y (on ENST00000375200 / NM_001282935.1; = p.H456Y on NM_032819.4) | Missense Mutation (SNP) | VAF 129/311 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61007881; called by muse, mutect2, varscan2
- ZNF471 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 178/440 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV57290091; called by muse, mutect2, varscan2
- ACE2 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 155/242 reads (64%) | SIFT tolerated (0.67); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ACTL8 | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 123/340 reads (36%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ADAMDEC1 | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 151/243 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADAMTS16 | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ADGB | c.1655C>T p.T552I | Missense Mutation (SNP) | VAF 124/328 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AQP10 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 262/508 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASB5 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 161/459 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ATP8B3 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 136/353 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- AXIN2 | c.395A>C p.K132T | Missense Mutation (SNP) | VAF 289/375 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- B4GALT6 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 98/234 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- B4GALT7 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 126/385 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- B4GALT7 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 123/382 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- C16orf78 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 112/325 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1F | c.3424G>A p.A1142T | Missense Mutation (SNP) | VAF 160/238 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- CACNA2D2 | c.3203G>A p.G1068D (on ENST00000479441 / NM_001174051.3; = p.G1061D on NM_006030.4) | Missense Mutation (SNP) | VAF 106/286 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CACNG8 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 118/320 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC42BPG | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 20/525 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLEC4F | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 154/413 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- CLMN | c.1904C>T p.S635F | Missense Mutation (SNP) | VAF 139/390 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CLSTN2 | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 75/199 reads (38%) | called by muse, varscan2
- COL24A1 | c.3593C>T p.T1198I | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- COL5A3 | c.4807G>A p.E1603K | Missense Mutation (SNP) | VAF 103/300 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL5A3 | c.3308G>A p.G1103E | Missense Mutation (SNP) | VAF 143/360 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL6A1 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 147/421 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYGD | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 74/252 reads (29%) | called by muse, mutect2, varscan2
- CSMD2 | c.9348G>A p.W3116* | Nonsense Mutation (SNP) | VAF 139/347 reads (40%) | called by muse, mutect2, varscan2
- DECR1 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 292/515 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DECR1 | c.158C>A p.P53Q | Missense Mutation (SNP) | VAF 287/510 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- DEFB123 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 113/277 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DENND1A | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 102/197 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- DNAH2 | c.12709C>T p.P4237S | Missense Mutation (SNP) | VAF 167/323 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAJC13 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 132/325 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DOK1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 185/450 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.348); called by muse, varscan2
- DRD5 | c.758A>C p.Q253P | Missense Mutation (SNP) | VAF 100/300 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- DSG4 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 129/361 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- DYNC2H1 | c.7811C>T p.S2604F | Missense Mutation (SNP) | VAF 89/293 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- E2F8 | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 163/455 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- EML5 | c.3415C>T p.L1139F | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ESPNL | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 180/386 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYA1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 84/418 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2
- F13B | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 187/338 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN2 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 139/391 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FERMT2 | c.1744A>G p.K582E | Missense Mutation (SNP) | VAF 120/297 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- FLRT3 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 171/264 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- FNDC1 | c.4190G>A p.G1397E | Missense Mutation (SNP) | VAF 97/273 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FPR2 | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 155/474 reads (33%) | called by muse, mutect2, varscan2
- FRAS1 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 122/317 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GABRG2 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- GALNT5 | c.1207A>T p.T403S | Missense Mutation (SNP) | VAF 137/356 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRB7 | c.647A>G p.H216R | Missense Mutation (SNP) | VAF 268/369 reads (73%) | SIFT tolerated (0.61); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- GSDMD | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 235/566 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GUCY2C | c.1577C>T p.T526I | Missense Mutation (SNP) | VAF 112/273 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- HDAC9 | c.2527C>T p.H843Y | Missense Mutation (SNP) | VAF 157/347 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- HUWE1 | c.5305C>T p.P1769S | Missense Mutation (SNP) | VAF 231/339 reads (68%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ICE1 | c.1675C>G p.P559A | Missense Mutation (SNP) | VAF 125/363 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- IGHV3-21 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 122/508 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.414); called by muse, varscan2
- IGSF22 | c.54C>G p.F18L | Missense Mutation (SNP) | VAF 139/355 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL1RL2 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- IRF9 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 212/591 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGAE | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 133/448 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ITIH6 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 198/319 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- KCNN3 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 366/661 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- KIAA0319 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 310/549 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA1109 | c.11561C>T p.T3854I | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KRT8 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 94/246 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- LAMA5 | c.3248C>G p.S1083W | Missense Mutation (SNP) | VAF 169/460 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- MAGEB6B | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 133/225 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAP1A | c.4799C>T p.S1600F | Missense Mutation (SNP) | VAF 124/321 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MTCH2 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 141/377 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MTNR1A | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 135/338 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- MTSS1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 402/664 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- MUC16 | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 141/375 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MUC2 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 163/394 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MUC4 | c.6692C>T p.S2231F | Missense Mutation (SNP) | VAF 185/1664 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); called by muse, varscan2
- NIPSNAP2 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 116/345 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP155 | c.3629G>C p.G1210A (on ENST00000231498 / NM_153485.3; = p.G1151A on NM_004298.4) | Missense Mutation (SNP) | VAF 123/359 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- OPN5 | c.471G>A p.W157* | Nonsense Mutation (SNP) | VAF 278/547 reads (51%) | called by muse, varscan2
- OR10J5 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 203/395 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- OSBPL2 | c.95G>A p.G32E (on ENST00000313733 / NM_144498.4; = p.G20E on NM_014835.4) | Missense Mutation (SNP) | VAF 136/387 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- PADI1 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 122/340 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- PALMD | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 123/277 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARM1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 180/473 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2
- PCSK5 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 150/243 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PDE7B | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 112/298 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PHACTR3 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 159/457 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1L1 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 206/352 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- PLA2G12B | c.510G>A p.W170* | Nonsense Mutation (SNP) | VAF 131/188 reads (70%) | called by muse, mutect2, varscan2
- PLEC | c.9217G>C p.E3073Q (on ENST00000322810 / NM_201380.4; = p.E2963Q on NM_000445.5) | Missense Mutation (SNP) | VAF 172/806 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRB2 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 180/604 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.186); called by muse, varscan2
- PRPF8 | c.5318C>T p.S1773F | Missense Mutation (SNP) | VAF 168/669 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RAD51B | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM27 | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 123/349 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RIF1 | c.5045G>A p.R1682K | Missense Mutation (SNP) | VAF 124/306 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCN9A | c.1314+1G>A p.X438_splice | Splice Site (SNP) | VAF 89/202 reads (44%) | called by muse, mutect2, varscan2
- SCRIB | c.4813G>A p.G1605S | Missense Mutation (SNP) | VAF 434/946 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); called by muse, varscan2
- SCRIB | c.4636C>T p.P1546S | Missense Mutation (SNP) | VAF 630/933 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA4A | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 172/646 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- SEMA6A | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 114/338 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINB13 | c.1139A>G p.N380S | Missense Mutation (SNP) | VAF 113/277 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SHC2 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 148/434 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SIGLEC5 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 160/428 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC22A16 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 106/419 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SLC2A13 | c.1694A>T p.H565L | Missense Mutation (SNP) | VAF 86/256 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SLC38A9 | c.341A>C p.Y114S | Missense Mutation (SNP) | VAF 100/234 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC8A1 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 155/460 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMG5 | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 304/522 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- SNX13 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 104/237 reads (44%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- SOBP | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 357/646 reads (55%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SORCS2 | c.3358G>A p.E1120K | Missense Mutation (SNP) | VAF 127/338 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- STAB2 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 145/399 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- STT3B | c.1619C>T p.T540I | Missense Mutation (SNP) | VAF 181/452 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYK | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 181/287 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TBC1D13 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 135/208 reads (65%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCF7L1 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 179/473 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TCIRG1 | c.1345del p.M450Wfs*78 | Frame Shift Del (DEL) | VAF 123/356 reads (35%) | called by mutect2, pindel, varscan2
- TDRD12 | c.3630A>G p.I1210M | Missense Mutation (SNP) | VAF 98/290 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- TECTA | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 130/352 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TFIP11 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 138/360 reads (38%) | called by muse, mutect2, varscan2
- TG | c.7441C>T p.P2481S | Missense Mutation (SNP) | VAF 124/648 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TKFC | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 152/391 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TLL2 | c.2722T>C p.F908L | Missense Mutation (SNP) | VAF 305/378 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRAV12-2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- TRIOBP | c.2218C>T p.Q740* | Nonsense Mutation (SNP) | VAF 193/518 reads (37%) | called by muse, mutect2, varscan2
- TTLL2 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 150/390 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- UBE3C | c.1048_1051del p.Q351Yfs*40 | Frame Shift Del (DEL) | VAF 96/334 reads (29%) | called by mutect2, pindel, varscan2
- UGT2B10 | c.785A>T p.N262I | Missense Mutation (SNP) | VAF 124/341 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UNC79 | c.3115C>T p.H1039Y (on ENST00000393151 / NM_001346218.2; = p.H862Y on NM_020818.5) | Missense Mutation (SNP) | VAF 171/465 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- UTP20 | c.5779A>G p.I1927V | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- VWA5A | c.279G>T p.Q93H | Missense Mutation (SNP) | VAF 160/387 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- WDR19 | c.2992G>A p.D998N | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- WDR97 | c.3385G>A p.D1129N | Missense Mutation (SNP) | VAF 168/702 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- XIRP1 | c.3139G>A p.G1047R | Missense Mutation (SNP) | VAF 171/515 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZCCHC8 | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 79/240 reads (33%) | called by muse, mutect2, varscan2
- ZDHHC24 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 171/464 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF251 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 619/952 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF345 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 192/495 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF888 | c.1702C>T p.H568Y | Missense Mutation (SNP) | VAF 130/349 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ABCC9 | c.2241G>A p.R747= | Silent (SNP) | VAF 90/243 reads (37%) | catalogued as COSV53963948, COSV53991305; called by muse, mutect2, varscan2
- AC119396.1 | c.543A>T p.G181= | Silent (SNP) | VAF 128/365 reads (35%) | called by muse, mutect2, varscan2
- ADGRB2 | c.3825C>T p.S1275= | Silent (SNP) | VAF 178/479 reads (37%) | catalogued as COSV57073801; called by muse, mutect2, varscan2
- AKAP13 | c.7860C>T p.A2620= (on ENST00000394518 / NM_007200.5; = p.A2624= on NM_006738.6) | Silent (SNP) | VAF 197/506 reads (39%) | called by muse, mutect2, varscan2
- ANK2 | c.11133C>T p.I3711= | Silent (SNP) | VAF 116/350 reads (33%) | catalogued as rs142441044; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANTXR1 | c.933C>T p.I311= | Silent (SNP) | VAF 130/354 reads (37%) | catalogued as COSV100362989; called by muse, mutect2, varscan2
- APCS | c.412C>T p.L138= | Silent (SNP) | VAF 179/592 reads (30%) | catalogued as COSV54817144, COSV54818932; called by muse, mutect2
- ARMC9 | c.1069C>T p.L357= | Silent (SNP) | VAF 141/322 reads (44%) | called by muse, mutect2, varscan2
- C10orf71 | c.3933C>T p.S1311= | Silent (SNP) | VAF 176/254 reads (69%) | called by muse, mutect2, varscan2
- CA2 | c.705A>G p.E235= | Silent (SNP) | VAF 333/495 reads (67%) | catalogued as COSV53408596; called by muse, mutect2, varscan2
- CACNA1A | c.1926C>T p.F642= | Silent (SNP) | VAF 122/301 reads (41%) | catalogued as rs772832553, COSV64191195; called by muse, mutect2, varscan2
- CACNG8 | c.333G>A p.T111= | Silent (SNP) | VAF 119/319 reads (37%) | called by muse, mutect2, varscan2
- CALR | c.477G>A p.K159= | Silent (SNP) | VAF 131/350 reads (37%) | called by muse, mutect2, varscan2
- CAPSL | c.252C>T p.F84= | Silent (SNP) | VAF 138/377 reads (37%) | catalogued as COSV101274333; called by muse, mutect2
- CCDC88C | c.444C>T p.D148= | Silent (SNP) | VAF 113/264 reads (43%) | called by muse, mutect2, varscan2
- CHKA | c.1254C>T p.F418= | Silent (SNP) | VAF 110/304 reads (36%) | catalogued as rs770317844, COSV55839143; called by muse, mutect2, varscan2
- CLMN | c.1905C>T p.S635= | Silent (SNP) | VAF 143/393 reads (36%) | catalogued as rs374137930; called by muse, mutect2, varscan2
- CLVS1 | c.735G>A p.R245= | Silent (SNP) | VAF 68/406 reads (17%) | catalogued as COSV57971824; called by muse, mutect2, varscan2
- COL11A2 | c.5202C>T p.F1734= (on ENST00000341947 / NM_080680.3; = p.F1627= on NM_080679.2) | Silent (SNP) | VAF 151/574 reads (26%) | called by muse, mutect2, varscan2
- COL5A1 | c.3144G>A p.G1048= | Silent (SNP) | VAF 128/218 reads (59%) | called by muse, mutect2, varscan2
- DENND1A | c.834C>T p.P278= | Silent (SNP) | VAF 99/194 reads (51%) | called by muse, mutect2, varscan2
- DNAH7 | c.11670G>A p.Q3890= | Silent (SNP) | VAF 161/393 reads (41%) | catalogued as COSV56786281; called by muse, mutect2, varscan2
- DNAJC17 | c.234C>T p.A78= | Silent (SNP) | VAF 121/323 reads (37%) | called by muse, mutect2, varscan2
- DRD5 | c.759G>A p.Q253= | Silent (SNP) | VAF 101/323 reads (31%) | called by muse, mutect2, varscan2
- DUOX2 | c.453C>T p.P151= | Silent (SNP) | VAF 203/497 reads (41%) | called by muse, mutect2, varscan2
- DUSP26 | c.570C>T p.P190= | Silent (SNP) | VAF 498/761 reads (65%) | called by muse, mutect2, varscan2
- ELSPBP1 | c.150C>T p.S50= | Silent (SNP) | VAF 159/443 reads (36%) | called by muse, mutect2, varscan2
- EPHA7 | c.2028G>A p.R676= | Silent (SNP) | VAF 205/616 reads (33%) | catalogued as rs760411632, COSV65181888, COSV65190079; called by muse, mutect2, varscan2
- ERN1 | c.2871C>T p.F957= | Silent (SNP) | VAF 307/390 reads (79%) | catalogued as rs1156935822, COSV70501740; called by muse, mutect2, varscan2
- FPR2 | c.483C>T p.F161= | Silent (SNP) | VAF 110/291 reads (38%) | catalogued as rs1032794466, COSV60672924; called by muse, mutect2, varscan2
- GABPB1 | c.1110G>A p.K370= | Silent (SNP) | VAF 140/381 reads (37%) | called by muse, mutect2, varscan2
- GDA | c.1215C>T p.S405= | Silent (SNP) | VAF 100/185 reads (54%) | catalogued as rs748523920; called by muse, mutect2, varscan2
- GLP2R | c.1065C>T p.F355= | Silent (SNP) | VAF 168/329 reads (51%) | catalogued as COSV52329480; called by muse, mutect2
- GSX2 | c.405C>T p.H135= | Silent (SNP) | VAF 196/610 reads (32%) | called by muse, mutect2
- HS1BP3 | c.225G>A p.E75= | Silent (SNP) | VAF 144/360 reads (40%) | catalogued as rs756188174; called by muse, mutect2, varscan2
- IDUA | c.471C>T p.S157= | Silent (SNP) | VAF 94/284 reads (33%) | called by muse, mutect2, varscan2
- INSRR | c.1071C>T p.N357= | Silent (SNP) | VAF 105/455 reads (23%) | called by muse, mutect2, varscan2
- ITPRID1 | c.2814G>A p.G938= | Silent (SNP) | VAF 117/287 reads (41%) | called by muse, mutect2, varscan2
- JPH3 | c.543C>T p.A181= | Silent (SNP) | VAF 203/555 reads (37%) | called by muse, mutect2, varscan2
- KCP | c.3507C>T p.F1169= (on ENST00000620378; = p.F1293= on NM_001366122.1) | Silent (SNP) | VAF 162/388 reads (42%) | called by muse, mutect2, varscan2
- KLHDC7A | c.1149G>A p.R383= | Silent (SNP) | VAF 144/404 reads (36%) | catalogued as rs1204379132; called by muse, mutect2, varscan2
- KLRC1 | c.496C>T p.L166= | Silent (SNP) | VAF 73/225 reads (32%) | called by muse, mutect2, varscan2
- KLRF1 | c.525T>C p.L175= | Silent (SNP) | VAF 113/310 reads (36%) | called by muse, mutect2, varscan2
- KRT39 | c.738G>A p.G246= | Silent (SNP) | VAF 287/355 reads (81%) | called by muse, mutect2, varscan2
- LAMA2 | c.4038A>G p.G1346= | Silent (SNP) | VAF 147/263 reads (56%) | called by muse, mutect2, varscan2
- LRRC4C | c.1293C>T p.S431= | Silent (SNP) | VAF 146/351 reads (42%) | catalogued as rs970904805, COSV53442079; called by muse, mutect2, varscan2
- MROH2A | c.1500C>T p.V500= | Silent (SNP) | VAF 103/313 reads (33%) | called by muse, mutect2, varscan2
- MTNR1A | c.117G>A p.V39= | Silent (SNP) | VAF 139/343 reads (41%) | catalogued as COSV56155807; called by muse, mutect2, varscan2
- MUC16 | c.39570G>A p.R13190= | Silent (SNP) | VAF 87/243 reads (36%) | catalogued as rs745525899, COSV66695139; called by muse, mutect2, varscan2
- MYCBP2 | c.8691C>T p.V2897= (on ENST00000357337; = p.V2935= on NM_015057.5) | Silent (SNP) | VAF 104/242 reads (43%) | called by muse, mutect2, varscan2
- MYOC | c.345G>A p.E115= | Silent (SNP) | VAF 204/633 reads (32%) | called by muse, mutect2, varscan2
- MYT1 | c.417C>T p.S139= | Silent (SNP) | VAF 144/389 reads (37%) | called by muse, mutect2, varscan2
- NOTCH3 | c.6117G>A p.L2039= | Silent (SNP) | VAF 245/571 reads (43%) | called by muse, mutect2, varscan2
- NOX5 | c.1308C>T p.I436= | Silent (SNP) | VAF 163/409 reads (40%) | catalogued as rs761300447; called by muse, mutect2, varscan2
- NUAK2 | c.471G>A p.R157= | Silent (SNP) | VAF 255/468 reads (54%) | catalogued as COSV100904130, COSV65682665; called by muse, mutect2, varscan2
- NUP214 | c.489C>T p.S163= | Silent (SNP) | VAF 162/236 reads (69%) | catalogued as rs1564175834; called by muse, mutect2, varscan2
- OR11L1 | c.819C>T p.I273= | Silent (SNP) | VAF 257/466 reads (55%) | catalogued as COSV100869410, COSV63313737; called by muse, mutect2, varscan2
- OR2J2 | c.231C>T p.S77= | Silent (SNP) | VAF 248/959 reads (26%) | called by muse, mutect2, varscan2
- OR2T3 | c.537C>T p.I179= | Silent (SNP) | VAF 292/449 reads (65%) | catalogued as rs965460968, COSV62083179; called by muse, mutect2, varscan2
- OR4S1 | c.876G>A p.V292= | Silent (SNP) | VAF 126/359 reads (35%) | catalogued as COSV60678744; called by muse, mutect2, varscan2
- OR6C1 | c.912G>A p.R304= | Silent (SNP) | VAF 84/270 reads (31%) | catalogued as COSV65573862; called by muse, mutect2, varscan2
- OR6T1 | c.186C>T p.F62= | Silent (SNP) | VAF 126/359 reads (35%) | catalogued as rs1487717554, COSV58305836; called by muse, mutect2, varscan2
- P2RY10 | c.762C>T p.I254= | Silent (SNP) | VAF 162/256 reads (63%) | catalogued as rs774939459; called by muse, mutect2, varscan2
- PCDHA7 | c.1899G>A p.T633= | Silent (SNP) | VAF 145/352 reads (41%) | catalogued as COSV65344998; called by muse, mutect2, varscan2
- PCDHB16 | c.198C>T p.I66= | Silent (SNP) | VAF 161/412 reads (39%) | called by muse, mutect2, varscan2
- PCDHB16 | c.567G>A p.R189= | Silent (SNP) | VAF 159/413 reads (38%) | catalogued as COSV53372775; called by muse, mutect2, varscan2
- PCNX3 | c.5151C>G p.L1717= | Silent (SNP) | VAF 119/303 reads (39%) | called by muse, mutect2, varscan2
- PGLYRP3 | c.231C>T p.T77= | Silent (SNP) | VAF 208/371 reads (56%) | called by muse, mutect2, varscan2
- PLB1 | c.2340C>T p.S780= | Silent (SNP) | VAF 148/381 reads (39%) | called by muse, mutect2, varscan2
- POLR2A | c.1128C>T p.D376= | Silent (SNP) | VAF 246/443 reads (56%) | called by muse, mutect2, varscan2
- PPP2R2B | c.276C>T p.I92= (on ENST00000394409; = p.I158= on NM_181674.2) | Silent (SNP) | VAF 138/388 reads (36%) | called by muse, mutect2, varscan2
- PROS1 | c.177C>T p.I59= | Silent (SNP) | VAF 131/364 reads (36%) | catalogued as rs764115962, COSV100820223; called by muse, mutect2, varscan2
- PRPF8 | c.5319C>T p.S1773= | Silent (SNP) | VAF 166/659 reads (25%) | called by muse, mutect2, varscan2
- RFPL4A | c.588C>T p.V196= | Silent (SNP) | VAF 64/498 reads (13%) | catalogued as COSV70455078; called by muse, mutect2, varscan2
- RFPL4AL1 | c.45A>T p.L15= | Silent (SNP) | VAF 124/774 reads (16%) | called by muse, mutect2, varscan2
- RFPL4AL1 | c.588C>T p.V196= | Silent (SNP) | VAF 72/754 reads (10%) | catalogued as rs1272847888, COSV59112758; called by muse, mutect2
- ROBO2 | c.2157C>T p.F719= | Silent (SNP) | VAF 110/257 reads (43%) | called by muse, mutect2, varscan2
- S1PR1 | c.780C>T p.I260= | Silent (SNP) | VAF 138/409 reads (34%) | catalogued as rs267597895, COSV59512780; called by muse, mutect2, varscan2
- SCN11A | c.292A>C p.R98= | Silent (SNP) | VAF 112/292 reads (38%) | called by muse, mutect2, varscan2
- SCN5A | c.2130G>A p.V710= | Silent (SNP) | VAF 141/436 reads (32%) | catalogued as rs866225028, COSV61123129; called by muse, mutect2, varscan2
- SECISBP2 | c.973T>C p.L325= | Silent (SNP) | VAF 113/171 reads (66%) | called by muse, mutect2, varscan2
- SEMA4C | c.1000T>C p.L334= | Silent (SNP) | VAF 136/350 reads (39%) | catalogued as rs773141612; called by muse, mutect2, varscan2
- SIAH3 | c.159C>G p.V53= | Silent (SNP) | VAF 202/451 reads (45%) | called by muse, mutect2, varscan2
- SLC19A1 | c.531G>C p.V177= | Silent (SNP) | VAF 25/538 reads (5%) | catalogued as rs1458452686; called by muse, mutect2
- SLC22A23 | c.24G>A p.E8= | Silent (SNP) | VAF 153/324 reads (47%) | called by muse, mutect2, varscan2
- SLC7A10 | c.198G>A p.L66= | Silent (SNP) | VAF 220/543 reads (41%) | called by muse, mutect2, varscan2
- SLC8A1 | c.2379C>T p.P793= | Silent (SNP) | VAF 154/457 reads (34%) | catalogued as rs763827563; called by muse, mutect2, varscan2
- SLIT2 | c.1878C>T p.F626= | Silent (SNP) | VAF 130/386 reads (34%) | catalogued as COSV56590259; called by muse, mutect2, varscan2
- SORL1 | c.1788C>T p.V596= | Silent (SNP) | VAF 164/427 reads (38%) | called by muse, mutect2, varscan2
- SPTA1 | c.6273C>T p.S2091= | Silent (SNP) | VAF 301/592 reads (51%) | catalogued as COSV63750195; called by muse, mutect2, varscan2
- STYK1 | c.897C>T p.L299= | Silent (SNP) | VAF 116/290 reads (40%) | called by muse, mutect2, varscan2
- TAS1R2 | c.702C>T p.I234= | Silent (SNP) | VAF 177/449 reads (39%) | catalogued as rs139202498; called by muse, mutect2, varscan2
- TAS2R41 | c.316C>T p.L106= | Silent (SNP) | VAF 140/345 reads (41%) | called by muse, mutect2, varscan2
- TESMIN | c.816C>T p.L272= | Silent (SNP) | VAF 75/235 reads (32%) | called by muse, mutect2, varscan2
- TLR5 | c.936G>A p.K312= | Silent (SNP) | VAF 156/529 reads (29%) | called by muse, mutect2, varscan2
- TNFSF9 | c.711C>T p.L237= | Silent (SNP) | VAF 161/410 reads (39%) | catalogued as rs758859325, COSV55539187; called by muse, mutect2, varscan2
- TPRG1L | c.495T>C p.I165= | Silent (SNP) | VAF 124/315 reads (39%) | called by muse, mutect2, varscan2
- TRMT2B | c.483C>T p.N161= | Silent (SNP) | VAF 193/285 reads (68%) | catalogued as rs1437763336; called by muse, mutect2, varscan2
- TTC12 | c.1392C>T p.T464= | Silent (SNP) | VAF 163/428 reads (38%) | catalogued as rs782421696, COSV59099761; called by muse, mutect2, varscan2
- TTN | c.24849C>T p.F8283= (on ENST00000591111; = p.F7356= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 161/375 reads (43%) | catalogued as rs1215707268, COSV60246938; called by muse, mutect2, varscan2
- UCKL1 | c.870C>T p.D290= | Silent (SNP) | VAF 144/373 reads (39%) | called by muse, mutect2, varscan2
- UMPS | c.1332C>T p.S444= | Silent (SNP) | VAF 122/315 reads (39%) | catalogued as rs112541424; called by muse, mutect2, varscan2
- USP27X | c.294C>T p.H98= | Silent (SNP) | VAF 205/332 reads (62%) | catalogued as rs1052203567; called by muse, mutect2, varscan2
- VARS1 | c.3216C>T p.F1072= | Silent (SNP) | VAF 298/957 reads (31%) | called by muse, mutect2, varscan2
- WDR27 | c.2025C>T p.S675= | Silent (SNP) | VAF 89/261 reads (34%) | called by muse, mutect2, varscan2
- ZAN | c.376C>T p.L126= | Silent (SNP) | VAF 223/537 reads (42%) | catalogued as rs1458198598; called by muse, mutect2, varscan2
- ZNF18 | c.342C>T p.T114= | Silent (SNP) | VAF 132/471 reads (28%) | called by muse, mutect2, varscan2
- ZNF345 | c.396C>T p.N132= | Silent (SNP) | VAF 193/496 reads (39%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-8517G>A | Intron (SNP) | VAF 110/294 reads (37%) | catalogued as COSV52536437; called by muse, mutect2, varscan2
- C14orf177 | n.485G>T | RNA (SNP) | VAF 164/431 reads (38%) | called by muse, mutect2, varscan2
- EPB41L3 | c.2350-833C>T | Intron (SNP) | VAF 127/317 reads (40%) | called by muse, mutect2, varscan2
- FBRSL1 | c.489+2063C>T | Intron (SNP) | VAF 161/440 reads (37%) | called by muse, mutect2, varscan2
- FBRSL1 | c.489+2064C>T | Intron (SNP) | VAF 160/435 reads (37%) | catalogued as rs1430949597; called by muse, mutect2, varscan2
- GLB1L3 | c.877-1954C>T | Intron (SNP) | VAF 100/294 reads (34%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-16524G>C | Intron (SNP) | VAF 12/261 reads (5%) | called by muse, mutect2
- KCNQ1 | c.1394-7922C>T | Intron (SNP) | VAF 84/244 reads (34%) | called by muse, mutect2, varscan2
- KLRF2 | chr12:9898965 G>A | 3'Flank (SNP) | VAF 130/354 reads (37%) | catalogued as rs1227020921; called by muse, mutect2, varscan2
- SCARB1 | c.*94C>T | 3'UTR (SNP) | VAF 136/328 reads (41%) | called by muse, mutect2, varscan2
- SPATA8 | n.286C>T | RNA (SNP) | VAF 153/374 reads (41%) | catalogued as COSV60705403; called by muse, mutect2, varscan2
- UQCRB | c.259-206C>T | Intron (SNP) | VAF 171/798 reads (21%) | called by muse, mutect2, varscan2
- VIPR2 | c.357+6733C>T | Intron (SNP) | VAF 189/508 reads (37%) | called by muse, mutect2, varscan2
- XPC | c.*485C>T | 3'UTR (SNP) | VAF 80/261 reads (31%) | called by muse, mutect2, varscan2
